TARGET case TARGET-30-PAIFXV — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4a47a989-5650-5366-9c83-4fa7e1deaa83

Demographics
Sex at birth: female; Race: white; Age at index: 5 years; Vital status: Dead; Days to death: 1,114 days (3.0 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 5.5 years (2,004 days); Year of diagnosis: 1995; Days to last follow up: 1,114 days (3.0 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Treatment given: Protocol identifier: 9341.
   Treatment given: Protocol identifier: 9342.
   Treatment given: Protocol identifier: 9047.
   Treatment given: Protocol identifier: P9462.
   Treatment given: Protocol identifier: 9340.

Follow-up (2 entries)
- Days to follow up: 630 days (1.7 years); Days to first event: 630 days (1.7 years); First event: Event.
- Days to follow up: 1,114 days (3.0 years); Year of follow up: 1998.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAIFXV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAIFXV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 1114
- Protocol: 9047, 9340, 9341, 9342, P9462
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.06
- Histology: Unfavorable
- ICDO Description: ABDOMEN/PERITONEUM OR RETROPERITONEUM
